Somatic mutation profile of tumor specimen TCGA-DB-A4XH-01A (aliquot TCGA-DB-A4XH-01A-11D-A27K-08) from TCGA case TCGA-DB-A4XH, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Frontal lobe; Tumor grade: G2; Age at diagnosis: 54.0 years (19,710 days).
Specimen TCGA-DB-A4XH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acea0c85-72e7-4e10-a85a-359aa3b0db5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A4XH-10A (Blood Derived Normal), aliquot TCGA-DB-A4XH-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98daa3a9-b8f7-498f-b1a1-a7df191d75ad

The open-access MAF lists 42 somatic variants for this specimen: 27 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 22, Silent 15, Splice Region 1, In Frame Ins 1, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 27/66 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AQP3 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs1162797219, COSV53047792; called by muse, mutect2
- CDC5L | c.1167G>C p.E389D | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV65175154; called by muse, mutect2, varscan2
- CHRNA1 | c.1103T>C p.I368T (on ENST00000261007 / NM_001039523.3; = p.I343T on NM_000079.4) | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV53681527; called by muse, mutect2, varscan2
- CYP4F12 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs369172315; called by mutect2, varscan2
- ITPR2 | c.5608G>C p.A1870P | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.503); catalogued as COSV67264233; called by muse, mutect2, varscan2
- KLHL18 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.15); catalogued as COSV51743887; called by muse, mutect2, varscan2
- OR1M1 | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as rs767614328, COSV70036378; called by muse, mutect2, varscan2
- OR5H2 | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 115/326 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV62349949; called by muse, mutect2, varscan2
- PAK5 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 91/232 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62020495; called by muse, mutect2, varscan2
- PARP1 | c.2458A>G p.N820D | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64689173; called by muse, mutect2, varscan2
- PHKB | c.2957C>A p.T986K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV54513813; called by muse, mutect2, varscan2
- RNF31 | c.980G>T p.R327L | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV53758257, COSV53758349; called by muse, mutect2, varscan2
- SMAD6 | c.1159A>T p.I387F | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56593274; called by muse, mutect2, varscan2
- SPANXD | c.225C>A p.N75K | Missense Mutation (SNP) | VAF 27/361 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1231092261, COSV65152275; called by muse, mutect2
- SRBD1 | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs758362125, COSV55395559; called by muse, mutect2, varscan2
- TBPL2 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs1342702013, COSV55971857; called by muse, mutect2
- TPST1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377712883; called by muse, mutect2, varscan2
- TRANK1 | c.6830G>A p.R2277H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs771383391, COSV57139827; called by muse, mutect2, varscan2
- VAMP5 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs745868707, COSV60498264; called by muse, mutect2
- WDR7 | c.3040C>T p.R1014* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as COSV54347469; called by muse, mutect2, varscan2
- ZBTB20 | c.1949A>G p.N650S (on ENST00000474710 / NM_001164342.2; = p.N577S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 111/248 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV61842535; called by muse, mutect2, varscan2
- ZP4 | c.1311G>A p.P437= | Splice Region (SNP) | VAF 24/71 reads (34%) | catalogued as rs746266633, COSV63910808, COSV63913201; called by muse, mutect2, varscan2
- NDUFA3 | c.179_185delinsGTT p.D60Gfs*21 | Frame Shift Del (DEL) | VAF 18/23 reads (78%) | called by pindel, varscan2*
- PIKFYVE | c.4419_4424dup p.S1475_S1476dup | In Frame Ins (INS) | VAF 24/100 reads (24%) | called by mutect2, pindel, varscan2
- SNX31 | c.1171-5_1171-2del p.X391_splice | Splice Site (DEL) | VAF 38/124 reads (31%) | called by pindel, varscan2
- SUPT20HL1 | c.74G>T p.R25I | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CELSR3 | c.5484G>A p.R1828= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV50839639; called by muse, mutect2
- COL27A1 | c.1428C>T p.T476= | Silent (SNP) | VAF 141/350 reads (40%) | catalogued as COSV61921268; called by muse, mutect2, varscan2
- DCN | c.693C>T p.N231= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV50006036; called by muse, mutect2
- HIPK4 | c.402C>T p.H134= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs774645030, COSV52518976; called by mutect2, varscan2
- LATS2 | c.573C>T p.Y191= | Silent (SNP) | VAF 13/132 reads (10%) | catalogued as rs768002766, COSV66873369; called by muse, mutect2
- MYO3A | c.4740G>A p.A1580= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs1181285977, COSV52150155; called by muse, mutect2, varscan2
- NAT8L | c.858C>G p.L286= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV59050720; called by muse, mutect2, varscan2
- PLAC1 | c.123C>G p.P41= | Silent (SNP) | VAF 138/316 reads (44%) | catalogued as rs1159509537, COSV63655035; called by muse, mutect2, varscan2
- PPP1R3F | c.600G>A p.P200= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as rs782106362, COSV50017655, COSV50020152; called by muse, mutect2, varscan2
- RNF31 | c.981A>T p.R327= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV53758352; called by muse, mutect2, varscan2
- SLC12A7 | c.1164G>A p.A388= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as rs138705098; called by muse, mutect2, varscan2
- SLC9A2 | c.855G>A p.G285= | Silent (SNP) | VAF 62/134 reads (46%) | catalogued as COSV52128555; called by muse, mutect2, varscan2
- TAS1R2 | c.1545C>T p.F515= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs1477056175, COSV100946197, COSV64743507; called by muse, mutect2, varscan2
- ZC3H12B | c.1386C>A p.V462= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as rs1395941159, COSV59046201; called by muse, mutect2
- ZNF280C | c.1438T>C p.L480= | Silent (SNP) | VAF 9/174 reads (5%) | catalogued as COSV63968448; called by muse, mutect2
